Somatic mutation profile of tumor specimen C3L-04082-01 (aliquot CPT0265570007) from CPTAC case C3L-04082, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.1 years (25,245 days).
Specimen C3L-04082-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd487b27-82e4-47ad-9b57-1a4f32675c30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04082-31 (Blood Derived Normal), aliquot CPT0264080002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/031cff3a-8983-49b1-9ed3-43da771e2a65

The open-access MAF lists 68 somatic variants for this specimen: 46 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 17, Nonsense Mutation 2, Intron 2, 5'UTR 2, RNA 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- G6PD | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 155/402 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs137852334, CM920285; ClinVar: other / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.204+3_204+6del p.X68_splice | Splice Site (DEL) | VAF 39/75 reads (52%) | catalogued as rs1567814632; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 52/88 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.645T>G p.S215R | Missense Mutation (SNP) | VAF 132/203 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520001, CD941799, COSV52752255, COSV52783847, COSV52798196; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF2 | c.1081C>T p.R361C (on ENST00000361247 / NM_001162383.2; = p.R333C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1327463595; called by muse, mutect2, varscan2
- ATP6V0A4 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 134/511 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs539497353, COSV59475611; called by muse, varscan2
- AWAT2 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs180949354, COSV52144204; called by muse, mutect2, varscan2
- CACNA1H | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 79/249 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs369630836; called by muse, mutect2, varscan2
- CPNE5 | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 66/233 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99782951; called by muse, mutect2, varscan2
- DCAF8L2 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 95/225 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs866230644, COSV70549990; called by muse, mutect2, varscan2
- DIDO1 | c.4651G>A p.A1551T | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs754379375; called by muse, varscan2
- GPKOW | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs782802093, COSV50242104; called by muse, mutect2, varscan2
- GRM2 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs369626642; called by muse, mutect2, varscan2
- GTF2E1 | c.257C>G p.T86S | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.241); catalogued as COSV52203490; called by muse, mutect2, varscan2
- HAUS2 | c.643_645del p.D215del | In Frame Del (DEL) | VAF 26/129 reads (20%) | catalogued as rs1264610146; called by mutect2, pindel, varscan2
- HIVEP2 | c.2822G>A p.R941H | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372565257; called by muse, mutect2, varscan2
- IGKV3-15 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 204/700 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs762878469; called by muse, mutect2, varscan2
- IQCH | c.2906G>A p.R969H | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs573462466, COSV60059631; called by muse, mutect2, varscan2
- ITGAM | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 132/344 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); catalogued as rs760528465, COSV99792813; called by muse, varscan2
- ITGAX | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs200458998, COSV51650268; called by muse, mutect2, varscan2
- KRT38 | c.1265C>T p.T422M | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs146369884; called by muse, mutect2, varscan2
- MMP13 | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 88/240 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as rs781983836, COSV52825345; called by muse, mutect2, varscan2
- OR9K2 | c.539G>T p.S180I (on ENST00000305377; = p.S158I on NM_001005243.1) | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs1399749461; called by muse, mutect2, varscan2
- OTUD7A | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 91/215 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763917042, COSV61044224; called by muse, mutect2, varscan2
- PCDH19 | c.1285G>A p.G429S | Missense Mutation (SNP) | VAF 115/256 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55263462; called by muse, mutect2, varscan2
- RBMX | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV57811684; called by muse, mutect2, varscan2
- SLC26A3 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 112/408 reads (27%) | catalogued as COSV60642629; called by muse, mutect2, varscan2
- SPTA1 | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 161/444 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.849); catalogued as rs201395636; called by muse, mutect2, varscan2
- WAS | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 154/400 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV100939496; called by muse, mutect2, varscan2
- XDH | c.2465G>A p.R822H | Missense Mutation (SNP) | VAF 138/374 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as rs777041375; called by muse, mutect2, varscan2
- ZNF292 | c.7967A>G p.N2656S | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs573895028; called by muse, mutect2, varscan2
- CENPJ | c.738A>T p.R246S | Missense Mutation (SNP) | VAF 112/320 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HCLS1 | c.591G>C p.Q197H | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- KLC2 | c.758A>C p.Q253P | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KLHL8 | c.23G>C p.S8T | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- MASP2 | c.1310C>A p.S437* | Nonsense Mutation (SNP) | VAF 36/71 reads (51%) | called by muse, mutect2, varscan2
- MGAT4C | c.896A>G p.K299R | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- MICAL3 | c.2776G>T p.G926C | Missense Mutation (SNP) | VAF 95/144 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- RTL3 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC7A11 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SSRP1 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- STRN3 | c.2015C>T p.S672L (on ENST00000357479 / NM_001083893.2; = p.S588L on NM_014574.4) | Missense Mutation (SNP) | VAF 77/145 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- STXBP5L | c.2798T>C p.V933A | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TRABD | c.503G>C p.G168A | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGT2A3 | c.791T>A p.F264Y | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- ZPBP | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ADCY10 | c.2721C>T p.H907= | Silent (SNP) | VAF 181/445 reads (41%) | catalogued as rs780180806, COSV63240875; called by muse, mutect2, varscan2
- AHI1 | c.462C>T p.H154= | Silent (SNP) | VAF 68/147 reads (46%) | catalogued as rs1265560624, COSV55627042; called by muse, mutect2, varscan2
- C20orf202 | c.234C>T p.D78= | Silent (SNP) | VAF 48/140 reads (34%) | catalogued as rs1485609653, COSV101272486; called by muse, mutect2, varscan2
- CDH19 | c.1170C>T p.G390= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as rs771241982, COSV100051616, COSV100052473; called by muse, mutect2, varscan2
- CFAP61 | c.300G>T p.L100= | Silent (SNP) | VAF 50/153 reads (33%) | called by muse, mutect2, varscan2
- COPS8 | c.108G>A p.V36= | Silent (SNP) | VAF 42/139 reads (30%) | catalogued as rs906850027, COSV62976604; called by muse, mutect2, varscan2
- HRNR | c.2025C>T p.Y675= | Silent (SNP) | VAF 231/613 reads (38%) | catalogued as rs770212794, COSV100913700; called by muse, mutect2, varscan2
- INHBA | c.546G>A p.P182= | Silent (SNP) | VAF 112/329 reads (34%) | catalogued as rs141733287, COSV54222714; called by muse, varscan2
- KCNA10 | c.1065G>A p.S355= | Silent (SNP) | VAF 154/376 reads (41%) | catalogued as rs566195238, COSV63904206; called by muse, mutect2, varscan2
- MUC4 | c.13254G>A p.T4418= (on ENST00000463781 / NM_018406.7; = p.T182= on NM_004532.6) | Silent (SNP) | VAF 64/122 reads (52%) | catalogued as rs754643337; called by muse, mutect2, varscan2
- MXRA5 | c.8016G>C p.T2672= | Silent (SNP) | VAF 56/191 reads (29%) | catalogued as COSV54241153; called by muse, mutect2, varscan2
- NDNF | c.975C>T p.T325= | Silent (SNP) | VAF 63/101 reads (62%) | catalogued as rs751244708; called by muse, mutect2, varscan2
- OR2T29 | c.228G>A p.A76= | Silent (SNP) | VAF 68/282 reads (24%) | catalogued as rs1356430111, COSV100148332; called by muse, mutect2, varscan2
- PCDHB14 | c.1665C>T p.N555= | Silent (SNP) | VAF 156/646 reads (24%) | called by muse, mutect2
- SIX2 | c.429C>T p.Y143= | Silent (SNP) | VAF 102/259 reads (39%) | catalogued as rs757228133, COSV100284208; called by muse, mutect2, varscan2
- SLC34A2 | c.1833C>T p.T611= | Silent (SNP) | VAF 136/212 reads (64%) | called by muse, varscan2
- TOE1 | c.1440C>T p.G480= | Silent (SNP) | VAF 97/228 reads (43%) | called by muse, mutect2, varscan2
- ADCY1 | c.1605+2141C>T | Intron (SNP) | VAF 51/272 reads (19%) | catalogued as rs570388484; called by muse, mutect2, varscan2
- ANXA2P2 | n.767T>A | RNA (SNP) | VAF 112/297 reads (38%) | called by muse, mutect2, varscan2
- FAIM | c.-23+1873C>T | Intron (SNP) | VAF 67/214 reads (31%) | catalogued as rs746197659; called by muse, mutect2, varscan2
- PANK2 | c.-1del | 5'UTR (DEL) | VAF 27/94 reads (29%) | called by mutect2, pindel, varscan2
- RNF128 | c.-6C>T | 5'UTR (SNP) | VAF 58/153 reads (38%) | catalogued as rs751360133; called by muse, mutect2, varscan2
